Somatic mutation profile of tumor specimen 0DG5AG from CCDI case PBBSZG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 9.0 years (3,296 days).
Specimen 0DG5AG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9c13ca3-6add-41c5-b978-0927b70c758c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG5AC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/588d8944-b7dd-4372-b487-3e25634c1dfb

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Intron 3, 3'UTR 2, Splice Site 2, Nonsense Mutation 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP9 | c.11431C>T p.R3811* (on ENST00000359028; = p.R3787* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 397/1211 reads (33%) | catalogued as rs183257184, COSV62342914; called by muse, mutect2, varscan2
- ANAPC4 | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 214/588 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs749197099; called by muse, mutect2, varscan2
- ARSD | c.1489G>A p.G497S | Missense Mutation (SNP) | VAF 119/322 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as rs749258093; called by muse, mutect2, varscan2
- DISP3 | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 137/310 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs377500218; called by muse, mutect2, varscan2
- EMC10 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs1371399198, COSV58541831; called by muse, mutect2, varscan2
- FER1L6 | c.4040G>T p.G1347V | Missense Mutation (SNP) | VAF 500/1618 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101206211; called by muse, mutect2, varscan2
- HDLBP | c.3130G>A p.E1044K | Missense Mutation (SNP) | VAF 111/421 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs756054968; called by muse, mutect2, varscan2
- LAIR1 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 143/371 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as rs757423062, COSV57306549; called by muse, mutect2, varscan2
- OR52K2 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 153/1078 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs759694235; called by muse, mutect2, varscan2
- PCDHA10 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 185/526 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as rs782304851, COSV56492965; called by muse, mutect2, varscan2
- PCIF1 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 171/604 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.353); catalogued as rs763052845; called by muse, mutect2, varscan2
- RGPD3 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 189/969 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754406473, COSV58746515; called by muse, varscan2
- YJU2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.37); catalogued as rs373312593, COSV53605530; called by muse, mutect2, varscan2
- ZBTB43 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 171/401 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV65095156; called by muse, mutect2, varscan2
- CDCA2 | c.284C>G p.A95G | Missense Mutation (SNP) | VAF 172/1506 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- CORO2A | c.1222C>G p.P408A | Missense Mutation (SNP) | VAF 153/381 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCAF8L1 | c.1031C>A p.P344H | Missense Mutation (SNP) | VAF 248/621 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH6 | c.4403G>A p.G1468D | Missense Mutation (SNP) | VAF 283/1021 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXL20 | c.330-1G>T p.X110_splice | Splice Site (SNP) | VAF 326/862 reads (38%) | called by muse, mutect2, varscan2
- GLA | c.88A>G p.R30G | Missense Mutation (SNP) | VAF 143/370 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYST | c.10477T>A p.F3493I | Missense Mutation (SNP) | VAF 175/382 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- NUDT8 | c.406-1G>A p.X136_splice | Splice Site (SNP) | VAF 89/372 reads (24%) | called by muse, mutect2, varscan2
- OR52B6 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 70/350 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB15 | c.1921G>C p.V641L | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRDM11 | c.176del p.T59Rfs*32 (on ENST00000530656 / NM_001359633.1; = p.T25Rfs*32 on NM_001256695.1) | Frame Shift Del (DEL) | VAF 178/816 reads (22%) | called by mutect2, varscan2
- SREBF1 | c.2331G>T p.W777C | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TC2N | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 223/566 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- APCDD1 | c.525C>T p.L175= | Silent (SNP) | VAF 162/463 reads (35%) | catalogued as rs1399059260, COSV100790032; called by muse, mutect2, varscan2
- C10orf90 | c.720G>T p.L240= | Silent (SNP) | VAF 252/550 reads (46%) | called by muse, mutect2, varscan2
- GRIN2D | c.3624G>T p.A1208= | Silent (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- PITPNM3 | c.1185C>T p.S395= | Silent (SNP) | VAF 197/530 reads (37%) | catalogued as rs772354449; called by muse, mutect2
- PLCB1 | c.3297C>A p.I1099= | Silent (SNP) | VAF 172/650 reads (26%) | catalogued as COSV62049022; called by mutect2, varscan2
- ARMCX4 | c.1038+885G>T | Intron (SNP) | VAF 134/364 reads (37%) | called by muse, varscan2
- CCDC88B | c.2959-85C>T | Intron (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1095370 C>T | 3'Flank (SNP) | VAF 58/332 reads (17%) | called by muse, mutect2, varscan2
- RREB1 | c.*5C>T | 3'UTR (SNP) | VAF 48/236 reads (20%) | called by muse, mutect2, varscan2
- SEC14L5 | c.*76C>A | 3'UTR (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- TGM2 | c.859+58G>T | Intron (SNP) | VAF 43/177 reads (24%) | called by muse, mutect2, varscan2
